Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A4P3, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A4P3-01A (Primary Tumor).

Gross Description: Esophagus of 13 x 3 cm in size, with ulcerating plate-like tumor of 5 x 4.5 cm in its size. Tissue of the stomach, 7 x 10 cm in size, is of normal structure.

Microscopic Description: Squamous cell carcinoma, G2, with invasion into muscularis propria, with lymphanginal infiltration.

Ten examined paraesophageal lymph nodes -- with follicular hyperplasia, one lymph node demonstrates metastases. One paratracheal lymph node is metastatic. Four examined paracardial lymph nodes -- with follicular hyperplasia.

Diagnosis Details: Tumor Features: Ulcerating, Tumor Extent: Muscularis Propria, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Thoracic esophagus (mid)

Tumor size: 4.5 x 0 x 5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: 2/15 positive for metastasis (10 -- paraesophageal; 1 -- paratracheal; 4 -- par 2/15)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, Squamous cell, NOS 8070/3
Path Site: esophagus, thoracic C15.1
CQCF esophagus, middle C15.4
hu
10/5/12

Reviewed (initials)	hu 10/4/12	

Source: NCI Genomic Data Commons file 9a1a37fb-461a-462b-ad98-071fc75f95f5 (TCGA-IG-A4P3.AEAAD0A0-642D-45F5-99C0-34DD484FC590.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).